Somatic mutation profile of tumor specimen TCGA-55-8620-01A (aliquot TCGA-55-8620-01A-11D-2393-08) from TCGA case TCGA-55-8620, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 60.5 years (22,091 days).
Specimen TCGA-55-8620-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df4ec609-f306-4e2e-a658-7604b16b2618.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8620-10A (Blood Derived Normal), aliquot TCGA-55-8620-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68b6cec2-1bbc-40c4-a374-e27915b124af

The open-access MAF lists 545 somatic variants for this specimen: 414 protein-altering or splice-affecting, 117 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 343, Silent 117, Nonsense Mutation 33, Frame Shift Del 17, Splice Site 14, RNA 6, Splice Region 3, Intron 3, 3'UTR 3, Frame Shift Ins 3, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.1249G>T p.G417W | Missense Mutation (SNP) | VAF 21/32 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50311993, COSV99408348; called by muse, mutect2, varscan2
- TP53 | c.838A>G p.R280G | Missense Mutation (SNP) | VAF 19/37 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753660142, COSV52662754, COSV52708728, COSV52851287; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.14845C>T p.R4949* (on ENST00000591111; = p.R4022* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/363 reads (10%) | catalogued as rs372277017; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA6 | c.1013T>A p.F338Y | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99447870; called by muse, mutect2, varscan2
- AC005324.2 | c.851A>T p.E284V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100372118; called by muse, mutect2, varscan2
- ACSM2A | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99525787; called by muse, mutect2, varscan2
- ADA2 | c.946C>T p.P316S (on ENST00000262607; = p.P75S on NM_177405.3) | Missense Mutation (SNP) | VAF 48/65 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV52831660; called by muse, mutect2, varscan2
- ADAMTS20 | c.3755C>A p.P1252H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs915020614, COSV101166419, COSV101166427; called by muse, mutect2, varscan2
- ADCY5 | c.3532G>T p.G1178W | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100568325; called by muse, mutect2, varscan2
- ADGRB3 | c.3418G>T p.G1140C | Missense Mutation (SNP) | VAF 111/260 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53255279; called by muse, mutect2, varscan2
- ADGRL2 | c.4039G>T p.G1347* (on ENST00000370717 / NM_001366005.1; = p.G1291* on NM_012302.4) | Nonsense Mutation (SNP) | VAF 38/128 reads (30%) | catalogued as COSV99591848; called by muse, mutect2, varscan2
- AHNAK2 | c.5812C>A p.P1938T | Missense Mutation (SNP) | VAF 98/312 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.506); catalogued as rs748363803, COSV100319161; called by muse, mutect2, varscan2
- AJAP1 | c.230del p.P77Rfs*76 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as COSV100982081; called by mutect2, pindel
- AKAP4 | c.2233G>T p.G745C | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV100654383; called by muse, mutect2, varscan2
- AL031777.2 | c.494A>T p.Q165L | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated, low confidence (0.12); catalogued as COSV100587293; called by muse, mutect2, varscan2
- ALKBH7 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99831810; called by muse, mutect2
- AMPH | c.1611G>T p.E537D | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV100343879; called by muse, varscan2
- ANPEP | c.830C>A p.T277K | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100263594, COSV55589161; called by muse, mutect2, varscan2
- AP3M1 | c.857G>C p.S286T | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100786788; called by muse, mutect2, varscan2
- APLNR | c.1025A>T p.K342M | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV57243429, COSV99951693; called by muse, mutect2, varscan2
- APOB | c.3507T>C p.Y1169= | Splice Region (SNP) | VAF 33/94 reads (35%) | catalogued as rs141763789; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ARHGEF10 | c.13G>C p.G5R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.095); catalogued as COSV100035771; called by muse, mutect2, varscan2
- ASPN | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100978695; called by muse, mutect2, varscan2
- ASTN1 | c.1439G>T p.G480V | Missense Mutation (SNP) | VAF 48/281 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV56061529, COSV56073522; called by muse, mutect2, varscan2
- ASTN2 | c.1603T>A p.C535S (on ENST00000313400 / NM_001365069.1; = p.C484S on NM_014010.5) | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100530756; called by muse, mutect2, varscan2
- ASXL2 | c.1678G>C p.D560H | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99712135; called by muse, mutect2, varscan2
- ATF1 | c.245A>T p.D82V | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs1036381239, COSV100016274; called by muse, mutect2, varscan2
- ATP10A | c.3363G>T p.W1121C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100791603; called by muse, mutect2, varscan2
- ATP2B2 | c.3341G>A p.R1114Q (on ENST00000352432; = p.R1080Q on NM_001683.5) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs370895383; called by muse, mutect2, varscan2
- ATP2B3 | c.1966G>T p.G656C | Missense Mutation (SNP) | VAF 36/47 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV99686084; called by muse, mutect2, varscan2
- ATP7B | c.902A>G p.Y301C | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99667015; called by muse, mutect2, varscan2
- ATR | c.2497G>T p.E833* | Nonsense Mutation (SNP) | VAF 35/93 reads (38%) | catalogued as COSV100638644, COSV63392006; called by muse, mutect2, varscan2
- BIRC3 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 89/300 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99680260; called by muse, mutect2, varscan2
- BSDC1 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.693); catalogued as COSV61981731; called by muse, mutect2, varscan2
- BSN | c.3215G>T p.R1072L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56514342, COSV99610002; called by muse, mutect2, varscan2
- C12orf40 | c.1724A>T p.H575L | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV100210840; called by muse, mutect2, varscan2
- C20orf194 | c.3193C>A p.L1065I | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV99331622; called by muse, mutect2, varscan2
- CACNA1A | c.2302C>T p.Q768* | Nonsense Mutation (SNP) | VAF 182/271 reads (67%) | catalogued as COSV100803336; called by muse, mutect2, varscan2
- CACNA2D4 | c.1455C>G p.I485M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV99766660; called by muse, mutect2, varscan2
- CASP6 | c.23G>C p.R8P | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99488895; called by muse, mutect2, varscan2
- CBL | c.2393C>A p.S798Y | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV50636749, COSV50668623; called by muse, mutect2, varscan2
- CD164 | c.427G>C p.G143R | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99248965; called by muse, mutect2, varscan2
- CD1B | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.049); catalogued as COSV100939316; called by muse, mutect2, varscan2
- CD6 | c.1943G>T p.G648V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.826); catalogued as COSV100533306; called by muse, mutect2, varscan2
- CD86 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.057); catalogued as COSV52606206; called by muse, mutect2, varscan2
- CDH12 | c.1847C>A p.A616E | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101203408; called by muse, mutect2, varscan2
- CELF4 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100611296, COSV58458191; called by muse, mutect2, varscan2
- CNOT2 | c.1202C>T p.S401L | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs747703636, COSV99973245; called by muse, mutect2, varscan2
- CNTN6 | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as COSV100611942; called by muse, mutect2, varscan2
- COL15A1 | c.3101G>A p.G1034E | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs779885966, COSV66642318; called by muse, mutect2, varscan2
- COL19A1 | c.1599G>T p.M533I | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV59567778; called by muse, mutect2, varscan2
- COL19A1 | c.2024C>A p.P675H | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59564803, COSV59571418; called by muse, mutect2, varscan2
- COL22A1 | c.4150G>A p.G1384R | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100281058; called by muse, mutect2
- COL22A1 | c.3220C>A p.Q1074K | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.973); catalogued as COSV100281059; called by muse, mutect2, varscan2
- COL6A6 | c.1663G>T p.E555* | Nonsense Mutation (SNP) | VAF 56/212 reads (26%) | catalogued as COSV100651020; called by muse, mutect2, varscan2
- COL9A2 | c.784G>T p.G262W | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV101025791; called by muse, mutect2, varscan2
- COL9A3 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100673619; called by muse, mutect2, varscan2
- CPNE6 | c.1458C>G p.D486E | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.147); catalogued as COSV53744016, COSV99393845; called by muse, mutect2, varscan2
- CPS1 | c.1883G>T p.G628V | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275599086, CM114329, COSV99244286; called by muse, mutect2, varscan2
- CPS1 | c.2563G>T p.A855S | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV99244287; called by muse, mutect2, varscan2
- CPXM2 | c.1327G>T p.G443* | Nonsense Mutation (SNP) | VAF 60/101 reads (59%) | catalogued as COSV99583467; called by muse, mutect2, varscan2
- CRB1 | c.2812C>A p.Q938K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100958089; called by muse, mutect2, varscan2
- CREBBP | c.1187C>G p.T396R | Missense Mutation (SNP) | VAF 83/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52132932, COSV52140415, COSV52141766; called by muse, mutect2, varscan2
- CRISP1 | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100237140, COSV59992969, COSV59995583; called by muse, mutect2, varscan2
- CRY2 | c.1073G>T p.W358L | Missense Mutation (SNP) | VAF 93/224 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV101314623; called by muse, mutect2, varscan2
- CSNK1D | c.506A>G p.E169G | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV99484810; called by muse, mutect2, varscan2
- CSNK1G3 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 76/135 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100631829; called by muse, mutect2, varscan2
- CST11 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 107/153 reads (70%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as COSV100776877; called by muse, mutect2, varscan2
- CTNNA2 | c.958T>A p.S320T | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); catalogued as COSV100786359; called by muse, mutect2, varscan2
- CUX2 | c.1621G>T p.G541C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs765232025, COSV99920929; called by muse, mutect2, varscan2
- CYFIP2 | c.3205G>T p.V1069F (on ENST00000616178 / NM_001291722.2; = p.V1044F on NM_014376.4) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.31); catalogued as COSV100557888; called by muse, mutect2, varscan2
- CYP2R1 | c.999A>T p.Q333H | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100585015; called by muse, mutect2, varscan2
- CYP3A4 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 110/230 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs72552797, COSV100315964, COSV60502124; called by muse, mutect2, varscan2
- CYSLTR2 | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 92/137 reads (67%) | SIFT tolerated (0.56); PolyPhen benign (0.154); catalogued as COSV99935430; called by muse, mutect2, varscan2
- DAO | c.913-1G>C p.X305_splice | Splice Site (SNP) | VAF 46/141 reads (33%) | catalogued as COSV99948903; called by muse, mutect2, varscan2
- DCAF12L1 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs907259332, COSV100948469, COSV64421371; called by muse, mutect2, varscan2
- DCAF12L1 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as COSV100948470; called by muse, mutect2, varscan2
- DDX11 | c.669A>C p.E223D | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV99300371; called by muse, mutect2, varscan2
- DDX31 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147990447; called by muse, mutect2, varscan2
- DEFB110 | c.151G>T p.G51* | Nonsense Mutation (SNP) | VAF 27/110 reads (25%) | catalogued as COSV101182429; called by muse, mutect2, varscan2
- DEPDC1 | c.1468A>G p.T490A | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100920506; called by muse, mutect2, varscan2
- DGKG | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV99404550; called by muse, mutect2, varscan2
- DHX16 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV99223962; called by muse, mutect2, varscan2
- DIS3 | c.1387-2A>G p.X463_splice | Splice Site (SNP) | VAF 263/289 reads (91%) | catalogued as COSV100900022; called by muse, mutect2, varscan2
- DLGAP2 | c.1113G>T p.W371C | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101422881; called by muse, mutect2, varscan2
- DNA2 | c.1557T>G p.I519M | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV100622866; called by muse, mutect2, varscan2
- DPP8 | c.791G>T p.R264I (on ENST00000341861 / NM_001320875.2; = p.R248I on NM_017743.6) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100202653; called by muse, mutect2, varscan2
- EID2 | c.490T>C p.Y164H | Missense Mutation (SNP) | VAF 116/209 reads (56%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); catalogued as COSV101180513; called by muse, mutect2, varscan2
- ENAM | c.354G>T p.Q118H | Missense Mutation (SNP) | VAF 70/112 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV101253363; called by muse, mutect2, varscan2
- ERBB4 | c.2354G>T p.G785V | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61484951; called by muse, mutect2, varscan2
- ERGIC2 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.281); catalogued as COSV100792044; called by muse, mutect2, varscan2
- EXOC1 | c.442A>G p.S148G | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100638053; called by muse, mutect2, varscan2
- EXOSC2 | c.284G>T p.R95M | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100964278; called by muse, mutect2, varscan2
- EXPH5 | c.2244G>T p.Q748H | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as COSV99762310; called by muse, mutect2, varscan2
- EYS | c.353C>G p.T118S | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.01); catalogued as COSV100677222; called by muse, mutect2, varscan2
- FAAH2 | c.957G>T p.M319I | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100887478; called by muse, mutect2, varscan2
- FAM234A | c.1188+1G>T p.X396_splice | Splice Site (SNP) | VAF 15/90 reads (17%) | catalogued as rs1305507872, COSV99396082; called by muse, mutect2, varscan2
- FAM91A1 | c.1892G>T p.R631L | Missense Mutation (SNP) | VAF 79/201 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs776231887, COSV100593839, COSV58236887; called by muse, mutect2, varscan2
- FAT3 | c.11695G>T p.G3899C | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53144604, COSV99971700; called by muse, mutect2, varscan2
- FAT4 | c.11432G>T p.G3811V | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT tolerated (0.41); PolyPhen benign (0.159); catalogued as COSV100630424; called by muse, mutect2, varscan2
- FBP2 | c.705G>T p.E235D | Missense Mutation (SNP) | VAF 107/234 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV100942227; called by muse, mutect2, varscan2
- FBXL7 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV100311063; called by muse, mutect2, varscan2
- FBXO43 | c.658A>T p.S220C | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV101413933; called by muse, mutect2, varscan2
- FCHO1 | c.336+1G>T p.X112_splice | Splice Site (SNP) | VAF 33/56 reads (59%) | catalogued as COSV53181693, COSV99406511; called by muse, mutect2, varscan2
- FGD5 | c.943C>A p.H315N | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99549456; called by muse, mutect2, varscan2
- FGD5 | c.1325C>A p.P442H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.137); catalogued as COSV99549458; called by muse, mutect2, varscan2
- FLRT2 | c.526G>T p.V176F | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.328); catalogued as rs777746741, COSV100421110; called by muse, mutect2, varscan2
- FLT1 | c.118C>A p.Q40K | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as COSV99167853; called by muse, mutect2, varscan2
- FNDC11 | c.838A>G p.K280E | Missense Mutation (SNP) | VAF 123/314 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100918847; called by muse, mutect2, varscan2
- FSHR | c.1430T>A p.L477Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100438220; called by muse, mutect2, varscan2
- FSTL5 | c.1201A>T p.S401C | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100061917, COSV100063019; called by muse, mutect2, varscan2
- GAL3ST4 | c.710C>A p.P237H | Missense Mutation (SNP) | VAF 171/250 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV100385654, COSV57588410; called by muse, mutect2, varscan2
- GARNL3 | c.1975G>A p.V659M | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs149591872; called by muse, mutect2, varscan2
- GART | c.145+1G>T p.X49_splice | Splice Site (SNP) | VAF 37/108 reads (34%) | catalogued as COSV99280091; called by muse, mutect2, varscan2
- GGA3 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419296368, COSV55456146; called by muse, mutect2
- GGCX | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142918177, COSV99289925; called by muse, mutect2, varscan2
- GLP2R | c.504+1G>T p.X168_splice | Splice Site (SNP) | VAF 30/47 reads (64%) | catalogued as COSV99302550; called by muse, mutect2, varscan2
- GLUD2 | c.77C>A p.S26* | Nonsense Mutation (SNP) | VAF 13/17 reads (76%) | catalogued as COSV100047136, COSV60152293; called by muse, mutect2, varscan2
- GPHB5 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV58486778; called by muse, mutect2, varscan2
- GPR158 | c.368A>T p.H123L | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100894382; called by muse, mutect2, varscan2
- GPR83 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.021); catalogued as rs1565182953, COSV99703987; called by muse, mutect2
- GPX5 | c.364G>T p.V122F | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101297287; called by muse, mutect2, varscan2
- GRAP2 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as rs976111985, COSV100703183, COSV59995241; called by muse, mutect2, varscan2
- GRID2 | c.2141G>T p.R714L | Missense Mutation (SNP) | VAF 65/102 reads (64%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV99947612; called by muse, mutect2, varscan2
- GRIK1 | c.1679C>A p.P560H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100518109; called by muse, mutect2, varscan2
- GRM6 | c.1520C>A p.S507Y | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99180012; called by muse, mutect2, varscan2
- GRM7 | c.1656G>C p.Q552H | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.606); catalogued as COSV100739050; called by muse, mutect2, varscan2
- GUCA1A | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99274339; called by muse, mutect2, varscan2
- GYS2 | c.1637C>A p.T546N | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.155); catalogued as COSV99680314; called by muse, mutect2, varscan2
- H2AP | c.161T>A p.L54H | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV61910822; called by muse, mutect2, varscan2
- HDAC9 | c.1436A>T p.Q479L | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.444); catalogued as COSV101287798; called by muse, mutect2, varscan2
- HECW2 | c.1955A>T p.Q652L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.027); catalogued as COSV99649241; called by muse, mutect2, varscan2
- HOATZ | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1170573923, COSV100239653; called by muse, mutect2, varscan2
- HSPH1 | c.2095G>A p.G699S | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100185215; called by muse, mutect2, varscan2
- HTR3D | c.451C>T p.Q151* (on ENST00000382489 / NM_001163646.2; = p.Q16* on NM_182537.3) | Nonsense Mutation (SNP) | VAF 35/80 reads (44%) | catalogued as COSV61915272; called by muse, mutect2, varscan2
- HUWE1 | c.11088G>C p.Q3696H | Missense Mutation (SNP) | VAF 81/125 reads (65%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.948); catalogued as COSV99474550; called by muse, mutect2, varscan2
- IGKV1-5 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs749425801; called by muse, mutect2, varscan2
- IL15 | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99650868; called by muse, mutect2, varscan2
- IL17RD | c.1220G>A p.W407* | Nonsense Mutation (SNP) | VAF 42/217 reads (19%) | catalogued as COSV99578337; called by muse, mutect2, varscan2
- IL22 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100048971; called by muse, mutect2, varscan2
- IL9R | c.759C>G p.C253W | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0.241); catalogued as COSV99730288; called by muse, mutect2, varscan2
- IRX3 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.168); catalogued as rs958132177, COSV61667883; called by muse, mutect2, varscan2
- ITGA6 | c.2929A>G p.R977G (on ENST00000442250; = p.R938G on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/300 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99906191; called by muse, mutect2, varscan2
- ITGBL1 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 231/352 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101095863; called by muse, mutect2
- JAG2 | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1365397948, COSV100078880; called by muse, mutect2
- JRK | c.319G>T p.V107L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs782530496, COSV101401175; called by muse, mutect2
- KALRN | c.6683A>T p.Q2228L (on ENST00000360013 / NM_001024660.4; = p.Q531L on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV99363148; called by muse, mutect2, varscan2
- KCNH6 | c.1297A>T p.K433* | Nonsense Mutation (SNP) | VAF 34/88 reads (39%) | catalogued as COSV100121296; called by muse, mutect2, varscan2
- KDM2A | c.2560G>T p.G854W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV100445861; called by muse, mutect2, varscan2
- KDM3B | c.2323G>A p.G775S | Missense Mutation (SNP) | VAF 98/447 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs755278940, COSV58692429; called by muse, varscan2
- KDM5C | c.983G>T p.R328L | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT tolerated (0.75); PolyPhen benign (0.062); catalogued as COSV100949534; called by muse, mutect2, varscan2
- KDR | c.1645+1G>C p.X549_splice | Splice Site (SNP) | VAF 245/745 reads (33%) | catalogued as COSV99818840; called by muse, mutect2, varscan2
- KIAA1755 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs1477543425, COSV99642778; called by muse, mutect2, varscan2
- KIAA1755 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 80/228 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.335); catalogued as rs761781113, COSV99642780; called by muse, mutect2, varscan2
- KLHL42 | c.569T>A p.M190K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV101179876; called by muse, mutect2, varscan2
- KRTAP10-3 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs373472330; called by muse, mutect2, varscan2
- KRTAP27-1 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV67001849; called by muse, mutect2, varscan2
- KRTAP5-1 | c.578C>A p.S193Y | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.367); catalogued as COSV66298960; called by muse, varscan2
- KRTAP6-2 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | PolyPhen probably damaging (1); catalogued as COSV100588953, COSV58182077; called by muse, mutect2, varscan2
- KYNU | c.982G>T p.G328* | Nonsense Mutation (SNP) | VAF 196/502 reads (39%) | catalogued as COSV99934093; called by muse, mutect2, varscan2
- KYNU | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 203/512 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99934096; called by muse, mutect2, varscan2
- LARP6 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100151103; called by muse, mutect2, varscan2
- LCT | c.4221C>A p.D1407E | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99930587; called by muse, mutect2, varscan2
- LELP1 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64202309; called by muse, mutect2, varscan2
- LINGO1 | c.1078A>T p.N360Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as COSV100796535; called by muse, mutect2, varscan2
- LPA | c.3082C>A p.P1028T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.346); catalogued as COSV100308198; called by muse, mutect2, varscan2
- LRFN5 | c.788G>T p.C263F | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99984629; called by muse, mutect2, varscan2
- LRP1B | c.4982G>A p.R1661H | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs756168629, COSV67189242, COSV67241168; called by muse, mutect2, varscan2
- LRP1B | c.4393G>A p.G1465S | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101261745; called by muse, mutect2, varscan2
- LRP1B | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV101261747; called by muse, varscan2
- LRP4 | c.3208G>A p.A1070T | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as COSV101066910; called by muse, mutect2, varscan2
- LRRC7 | c.3428G>T p.S1143I (on ENST00000651989 / NM_001370785.2; = p.S1110I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as COSV50446692, COSV99230201; called by muse, mutect2, varscan2
- LRRIQ1 | c.3727A>C p.T1243P | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101280738; called by muse, mutect2, varscan2
- LRRK2 | c.286A>G p.M96V | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs758347680, COSV100111270; called by muse, mutect2, varscan2
- LRRTM1 | c.1523G>T p.G508V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54445840, COSV99703317; called by muse, mutect2, varscan2
- LRRTM4 | c.1047G>T p.K349N | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as rs1396648231, COSV101297750; called by muse, mutect2
- LTBP2 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs374812477; called by muse, mutect2, varscan2
- MAP2 | c.4387+1G>T p.X1463_splice | Splice Site (SNP) | VAF 15/67 reads (22%) | catalogued as rs1309363165, COSV99561936; called by muse, mutect2, varscan2
- MCM3 | c.1566G>T p.E522D (on ENST00000229854 / NM_001366374.2; = p.E512D on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.856); catalogued as COSV100009126; called by muse, mutect2, varscan2
- MCPH1 | c.521G>C p.S174T | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); catalogued as COSV100766184; called by muse, mutect2, varscan2
- MDGA2 | c.1518C>G p.S506R (on ENST00000399232 / NM_001113498.2; = p.S208R on NM_182830.4) | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.94); catalogued as COSV100638640, COSV62105937; called by muse, mutect2, varscan2
- MED12L | c.5134T>C p.Y1712H | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV99854959; called by muse, mutect2, varscan2
- MEIS1 | c.995A>T p.Q332L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99715867; called by muse, mutect2, varscan2
- MIOS | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 67/117 reads (57%) | catalogued as COSV100402984; called by muse, mutect2, varscan2
- MMP25 | c.603C>G p.H201Q | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs765302161, COSV100339644; called by muse, mutect2, varscan2
- MOS | c.217T>A p.S73T | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as COSV100323042; called by muse, mutect2, varscan2
- MUC16 | c.35558A>T p.H11853L | Missense Mutation (SNP) | VAF 76/115 reads (66%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV101201941; called by muse, mutect2, varscan2
- MUC17 | c.1446G>T p.Q482H | Missense Mutation (SNP) | VAF 592/845 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs774759850, COSV100075334, COSV60296375; called by muse, mutect2, varscan2
- MUC4 | c.2411C>A p.T804N | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.413); catalogued as COSV100642428; called by muse, mutect2, varscan2
- MUC5AC | c.13994G>T p.C4665F | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); catalogued as COSV100611628; called by muse, mutect2, varscan2
- MXRA5 | c.1829G>C p.S610T | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.334); catalogued as COSV99479624; called by muse, mutect2, varscan2
- MYH1 | c.3880C>A p.Q1294K | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV99877042; called by muse, mutect2, varscan2
- MYO9B | c.3878G>A p.G1293D | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as COSV101262003; called by muse, mutect2, varscan2
- NAALADL2 | c.1726G>C p.D576H | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101495514; called by muse, mutect2, varscan2
- NAT10 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs201610017, COSV99140557; called by muse, mutect2, varscan2
- NAV3 | c.3188G>A p.S1063N | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99896322; called by muse, mutect2, varscan2
- NCAPD2 | c.2437C>T p.Q813* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100217491; called by muse, mutect2, varscan2
- NCKAP5 | c.4003C>A p.L1335I | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV100494620; called by muse, mutect2, varscan2
- NECTIN3 | c.1369G>T p.V457F | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100162789; called by muse, mutect2, varscan2
- NFASC | c.3294C>A p.Y1098* (on ENST00000339876 / NM_001378329.1; = p.Y1027* on NM_015090.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/98 reads (21%) | catalogued as COSV100365989; called by muse, mutect2, varscan2
- NFRKB | c.3091G>T p.A1031S (on ENST00000446488 / NM_001143835.2; = p.A1056S on NM_006165.3) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.031); catalogued as COSV100452117; called by muse, mutect2, varscan2
- NFS1 | c.1249G>T p.E417* | Nonsense Mutation (SNP) | VAF 30/108 reads (28%) | catalogued as COSV100932025, COSV65054255; called by muse, mutect2, varscan2
- NLRP1 | c.2995G>T p.D999Y | Missense Mutation (SNP) | VAF 142/281 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV99335659; called by muse, mutect2, varscan2
- NLRP4 | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100017297, COSV56712882; called by muse, mutect2, varscan2
- NLRP5 | c.3242G>T p.G1081V | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs993605597, COSV101173910; called by muse, mutect2, varscan2
- NMBR | c.975C>A p.Y325* | Nonsense Mutation (SNP) | VAF 34/142 reads (24%) | catalogued as COSV99237562; called by muse, mutect2, varscan2
- NOL6 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1033076164, COSV99955274; called by muse, mutect2, varscan2
- NOX3 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV99343700; called by muse, mutect2, varscan2
- NOX3 | c.365T>A p.F122Y | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV99343702; called by muse, mutect2, varscan2
- NPAP1 | c.1089G>T p.E363D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.79); catalogued as COSV100276297; called by mutect2, varscan2
- NPAP1 | c.2080C>A p.P694T | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT tolerated (0.88); PolyPhen benign (0.026); catalogued as COSV100276298; called by muse, mutect2, varscan2
- NPBWR2 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs141331386, COSV100871152; called by muse, mutect2, varscan2
- NPFFR1 | c.403G>T p.V135L | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV99525041; called by muse, mutect2, varscan2
- NPSR1 | c.344C>A p.T115K | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100707269; called by muse, mutect2, varscan2
- NTN4 | c.1142A>T p.D381V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100643888; called by muse, mutect2, varscan2
- NTNG1 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 104/380 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99639823; called by muse, mutect2, varscan2
- OBSCN | c.22919C>A p.P7640H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100806096; called by muse, mutect2, varscan2
- OCA2 | c.738G>T p.R246S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100668794; called by muse, mutect2, varscan2
- OR1N1 | c.631T>C p.C211R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as rs758789377, COSV100509861; called by mutect2, varscan2
- OR2AE1 | c.904A>G p.R302G | Missense Mutation (SNP) | VAF 170/247 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV100318432; called by muse, mutect2, varscan2
- OR2G2 | c.530T>A p.V177E | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100190035; called by muse, mutect2, varscan2
- OR2T2 | c.322C>A p.L108M | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV100737810; called by muse, mutect2
- OR4A15 | c.522C>A p.N174K | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.309); catalogued as COSV100124384; called by muse, mutect2, varscan2
- OR4A47 | c.812T>A p.V271E | Missense Mutation (SNP) | VAF 152/317 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101487118; called by muse, mutect2, varscan2
- OR4C15 | c.1034A>T p.K345M (on ENST00000314644; = p.K291M on NM_001001920.2) | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.959); catalogued as rs1284689040, COSV100116165; called by muse, mutect2, varscan2
- OR5A1 | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 125/298 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0.065); catalogued as COSV100118489; called by muse, mutect2, varscan2
- OR5AP2 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 140/309 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV100266466, COSV104407484; called by muse, mutect2, varscan2
- OR5M8 | c.895G>C p.A299P | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59118524; called by muse, mutect2, varscan2
- OR5W2 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV60614774, COSV60615520; called by muse, mutect2, varscan2
- ORC4 | c.1301G>C p.S434T | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.115); catalogued as COSV99605230; called by muse, mutect2, varscan2
- OSBP | c.899A>T p.Q300L | Missense Mutation (SNP) | VAF 78/180 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99803470; called by muse, mutect2, varscan2
- OSBPL11 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.95); PolyPhen benign (0.041); catalogued as rs200816516, COSV99954435; called by muse, mutect2, varscan2
- OTOF | c.5623G>T p.V1875L (on ENST00000272371 / NM_194248.3; = p.V1108L on NM_004802.4) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV99719188; called by muse, mutect2, varscan2
- PADI4 | c.1274T>A p.L425Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100966943; called by muse, mutect2, varscan2
- PAF1 | c.168C>T p.N56= | Splice Region (SNP) | VAF 7/162 reads (4%) | catalogued as COSV99656081; called by muse, mutect2
- PAIP2B | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.026); catalogued as COSV99731568, COSV99731851; called by muse, mutect2
- PBX3 | c.880A>T p.K294* | Nonsense Mutation (SNP) | VAF 35/81 reads (43%) | catalogued as COSV100655611; called by muse, mutect2, varscan2
- PCDHB2 | c.775G>T p.V259F | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); catalogued as rs782061095, COSV52029412, COSV99523661; called by muse, mutect2, varscan2
- PCDHB8 | c.714T>A p.D238E | Missense Mutation (SNP) | VAF 114/565 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as COSV99177486; called by muse, mutect2, varscan2
- PCDHB9 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as rs1554283220; called by muse, mutect2, varscan2
- PDE11A | c.1886G>T p.R629L | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV53691028, COSV53699752; called by muse, mutect2, varscan2
- PEG3 | c.4324G>T p.E1442* | Nonsense Mutation (SNP) | VAF 21/127 reads (17%) | catalogued as COSV99690661; called by muse, mutect2, varscan2
- PGLYRP1 | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV50517628; called by muse, mutect2, varscan2
- PHOX2B | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV56931607, COSV99891734; called by muse, mutect2, varscan2
- PIF1 | c.1288G>T p.D430Y | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99165345; called by muse, mutect2, varscan2
- PIF1 | c.1287G>T p.Q429H | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV99165356; called by muse, mutect2, varscan2
- PIWIL4 | c.409A>G p.R137G | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV54408438; called by muse, mutect2, varscan2
- PKD1 | c.6139G>T p.G2047C | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99239191; called by muse, mutect2, varscan2
- PKHD1L1 | c.5645G>T p.C1882F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101006921, COSV65738872; called by muse, mutect2, varscan2
- PLA2G4A | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100820762, COSV66552455; called by muse, mutect2, varscan2
- PLAGL1 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs749708141, COSV52786342; called by muse, mutect2, varscan2
- PLB1 | c.2711A>T p.N904I | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100580043; called by muse, mutect2, varscan2
- PLEC | c.6319G>C p.A2107P (on ENST00000322810 / NM_201380.4; = p.A1997P on NM_000445.5) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as COSV100519693; called by muse, mutect2
- PLG | c.505C>G p.P169A | Missense Mutation (SNP) | VAF 96/237 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as CM142812, COSV99805183; called by muse, mutect2, varscan2
- PLPPR3 | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200639651, COSV100608761; called by muse, mutect2, varscan2
- PLPPR4 | c.1338G>T p.Q446H | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100926961; called by muse, mutect2, varscan2
- PLXDC2 | c.980-2A>T p.X327_splice | Splice Site (SNP) | VAF 80/190 reads (42%) | catalogued as COSV101023311; called by muse, mutect2, varscan2
- PLXND1 | c.4070G>T p.R1357L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100140499, COSV60718169; called by muse, mutect2
- PMS1 | c.790A>T p.S264C | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); catalogued as rs751238299, COSV99066309; called by muse, mutect2, varscan2
- PNKP | c.1439A>G p.Y480C | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.762); catalogued as COSV99682089; called by muse, mutect2, varscan2
- PNLIPRP2 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100078017; called by muse, mutect2
- PNMA8B | c.1112C>A p.P371H | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs967833590, COSV100885539; called by muse, mutect2, varscan2
- PPARG | c.601G>C p.V201L (on ENST00000287820 / NM_015869.5; = p.V171L on NM_005037.7) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.99); catalogued as COSV99826839; called by muse, mutect2, varscan2
- PPM1K | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99901193; called by muse, mutect2, varscan2
- PPP1R21 | c.2134G>T p.A712S (on ENST00000294952 / NM_001135629.3; = p.A701S on NM_152994.5) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773465448, COSV99682678; called by muse, mutect2, varscan2
- PPP2R2C | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV100067399; called by muse, mutect2, varscan2
- PPP6R2 | c.1953G>A p.M651I (on ENST00000216061 / NM_001365836.1; = p.M624I on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/98 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs780846862, COSV99324935; called by muse, mutect2, varscan2
- PRAMEF1 | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100180279; called by muse, mutect2, varscan2
- PRDM9 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 94/221 reads (43%) | catalogued as COSV99691388; called by muse, mutect2, varscan2
- PRELID3B | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99718230; called by mutect2, varscan2
- PRLR | c.1660G>C p.D554H | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs767785645, COSV99184852; called by muse, mutect2, varscan2
- PROKR2 | c.197T>C p.V66A | Missense Mutation (SNP) | VAF 63/109 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV99450705; called by muse, mutect2, varscan2
- PTGS2 | c.975G>C p.E325D | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100821858; called by muse, mutect2, varscan2
- PTPRK | c.2794G>T p.V932L (on ENST00000368215 / NM_001291984.2; = p.V933L on NM_002844.4) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100951676; called by muse, mutect2, varscan2
- QSER1 | c.2314G>T p.G772C (on ENST00000399302; = p.G901C on NM_001076786.3) | Missense Mutation (SNP) | VAF 107/324 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV101234983; called by muse, mutect2, varscan2
- RABGGTA | c.1209G>T p.E403D | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99253278; called by muse, mutect2
- RAVER2 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1185047645, COSV53806381, COSV99605743; called by muse, mutect2, varscan2
- RBL2 | c.716A>C p.N239T | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100044119; called by muse, mutect2, varscan2
- RBM10 | c.2092G>T p.E698* | Nonsense Mutation (SNP) | VAF 29/50 reads (58%) | catalogued as COSV61307701; called by muse, mutect2, varscan2
- RBM43 | c.83G>C p.S28T | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.035); catalogued as COSV100508684; called by muse, mutect2, varscan2
- RCOR3 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65365740; called by muse, mutect2, varscan2
- REN | c.1030A>G p.T344A | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.288); catalogued as COSV99689754; called by muse, mutect2
- RESF1 | c.2630A>T p.Q877L | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100440678; called by muse, mutect2, varscan2
- RFX4 | c.51G>T p.W17C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100774308; called by muse, mutect2
- RGS9 | c.1132A>C p.K378Q | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.936); catalogued as COSV99288153; called by muse, mutect2, varscan2
- RIMS2 | c.2815C>A p.P939T (on ENST00000666250 / NM_001348490.2; = p.P747T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs746467834, COSV51676458, COSV99202274; called by muse, mutect2, varscan2
- RIMS2 | c.2816C>A p.P939H (on ENST00000666250 / NM_001348490.2; = p.P747H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV51654841; called by muse, mutect2, varscan2
- RIMS2 | c.3803G>C p.G1268A | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as COSV99202303; called by muse, mutect2, varscan2
- RNASE9 | c.489C>G p.Y163* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100141422; called by muse, mutect2, varscan2
- ROBO2 | c.406C>G p.R136G | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100170354, COSV59947326; called by muse, mutect2, varscan2
- ROBO4 | c.1424G>C p.G475A | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV100127894; called by muse, mutect2, varscan2
- RSPO2 | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV52654795, COSV99410522; called by muse, mutect2, varscan2
- SCGB1A1 | c.103C>A p.L35I | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99545961; called by muse, mutect2, varscan2
- SDHA | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 55/249 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV99372270; called by muse, mutect2, varscan2
- SDHAF2 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV100074061; called by muse, mutect2, varscan2
- SEC24A | c.805G>T p.G269C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100524716; called by muse, mutect2, varscan2
- SEMA3A | c.1495-1G>T p.X499_splice | Splice Site (SNP) | VAF 24/37 reads (65%) | catalogued as COSV99547326, COSV99548155; called by muse, mutect2, varscan2
- SERPINI1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.927); catalogued as COSV99855471; called by muse, mutect2, varscan2
- SEZ6L | c.3052A>G p.R1018G | Missense Mutation (SNP) | VAF 121/212 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV99963084; called by muse, mutect2, varscan2
- SGIP1 | c.1314T>C p.S438= | Splice Region (SNP) | VAF 116/331 reads (35%) | catalogued as COSV99393135; called by muse, mutect2, varscan2
- SH2D4B | c.586C>A p.Q196K | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100214285; called by muse, mutect2, varscan2
- SHOC1 | c.2546-2A>C p.X849_splice | Splice Site (SNP) | VAF 35/69 reads (51%) | catalogued as COSV100598078; called by muse, mutect2, varscan2
- SLC12A6 | c.2141A>G p.Y714C (on ENST00000354181 / NM_001365088.1; = p.Y663C on NM_005135.2) | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99273553; called by muse, mutect2, varscan2
- SLC16A10 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100921001; called by muse, mutect2, varscan2
- SLC17A2 | c.656C>A p.T219N | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV99615059; called by muse, mutect2, varscan2
- SLC25A16 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.265); catalogued as rs747504150, COSV56263722, COSV99770293; called by muse, mutect2, varscan2
- SLC30A8 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69969716; called by muse, mutect2, varscan2
- SLC38A7 | c.104C>G p.P35R | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.18); PolyPhen benign (0.221); catalogued as COSV99543972; called by muse, mutect2, varscan2
- SLC4A1 | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs777827818, COSV52259238, COSV52262464; called by muse, mutect2, varscan2
- SLC7A3 | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99979689, COSV99979886; called by muse, mutect2, varscan2
- SLC8B1 | c.194G>A p.C65Y | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99176846; called by muse, mutect2, varscan2
- SLC9A4 | c.2216G>T p.G739V | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1347224494, COSV54837957, COSV99763634; called by muse, mutect2, varscan2
- SLITRK4 | c.1241C>A p.T414K | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100567546; called by muse, mutect2, varscan2
- SMG6 | c.2147A>C p.K716T | Missense Mutation (SNP) | VAF 76/152 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV99558871; called by muse, mutect2, varscan2
- SOGA1 | c.3560G>T p.R1187L | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.356); catalogued as rs369369459, COSV99415686; called by muse, mutect2, varscan2
- SORCS3 | c.1750C>A p.L584I | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100865689, COSV63815326; called by muse, mutect2, varscan2
- SPACA1 | c.611-2A>G p.X204_splice | Splice Site (SNP) | VAF 60/149 reads (40%) | catalogued as COSV99389815; called by muse, mutect2, varscan2
- SPAM1 | c.694C>A p.P232T | Missense Mutation (SNP) | VAF 98/164 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV99773572; called by muse, mutect2, varscan2
- SPARCL1 | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 272/459 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV99215982; called by muse, mutect2, varscan2
- SPEG | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 11/88 reads (13%) | catalogued as COSV100405834; called by muse, mutect2, varscan2
- SPESP1 | c.689T>A p.I230N | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1286699382, COSV52984364; called by muse, mutect2, varscan2
- SPG11 | c.5090A>G p.E1697G | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV99969756; called by muse, mutect2, varscan2
- SPHK2 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs763254269, COSV99709678; called by muse, mutect2, varscan2
- SPINDOC | c.914G>T p.R305L | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV53691929, COSV99588807; called by muse, mutect2, varscan2
- SPTA1 | c.4822C>A p.R1608S | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs1279138950, COSV100935674, COSV63751266; called by muse, mutect2, varscan2
- SPTA1 | c.4570T>G p.C1524G | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.561); catalogued as COSV100935675; called by muse, mutect2, varscan2
- SRSF4 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV100861449; called by muse, mutect2, varscan2
- SS18 | c.83A>G p.N28S | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52262988; called by muse, mutect2, varscan2
- STX17 | c.130A>T p.R44W | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99408190; called by muse, mutect2, varscan2
- SV2A | c.286G>T p.G96W | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100975294; called by muse, mutect2, varscan2
- SYN2 | c.1099C>A p.L367M | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101413893; called by muse, mutect2, varscan2
- SYT4 | c.1261G>A p.V421M | Missense Mutation (SNP) | VAF 131/331 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs775106428, COSV54901695; called by muse, mutect2, varscan2
- TAAR6 | c.9C>A p.S3R | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs868080405, COSV51582901; called by muse, mutect2, varscan2
- TECPR2 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100850242; called by muse, mutect2, varscan2
- TF | c.1467G>C p.K489N | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as COSV53925538, COSV99396487; called by muse, mutect2, varscan2
- TMC5 | c.2400C>G p.I800M (on ENST00000396229 / NM_001105248.1; = p.I554M on NM_024780.5) | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as COSV99572921; called by muse, mutect2, varscan2
- TMEM200A | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99760182; called by muse, mutect2, varscan2
- TMPRSS15 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99519497; called by muse, mutect2, varscan2
- TNN | c.2833C>A p.P945T | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99513201; called by muse, mutect2, varscan2
- TOP3A | c.715A>G p.I239V | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.735); catalogued as COSV100329345; called by muse, mutect2, varscan2
- TRAF7 | c.1444G>C p.V482L | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100399885; called by muse, mutect2, varscan2
- TREX2 | c.622C>T p.R208W (on ENST00000334497; = p.R165W on NM_080701.3) | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs781931982, COSV100444362; called by muse, mutect2, varscan2
- TRH | c.454C>A p.Q152K | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100234973; called by muse, mutect2, varscan2
- TRIM42 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs762886107, COSV53887882; called by muse, mutect2, varscan2
- TRIM58 | c.657G>T p.K219N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV100825343; called by muse, mutect2
- TRIM58 | c.1288G>T p.G430* | Nonsense Mutation (SNP) | VAF 36/218 reads (17%) | catalogued as COSV100825344; called by muse, mutect2, varscan2
- TRPM3 | c.1756T>A p.C586S (on ENST00000357533 / NM_001366142.2; = p.C419S on NM_020952.6) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.034); catalogued as COSV100678909; called by muse, mutect2, varscan2
- TRUB1 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV100076239; called by muse, mutect2, varscan2
- TSHZ1 | c.2288C>T p.P763L (on ENST00000580243 / NM_001308210.2; = p.P718L on NM_005786.6) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100433967; called by muse, mutect2, varscan2
- TSHZ3 | c.1438G>T p.V480F | Missense Mutation (SNP) | VAF 195/429 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV99551091; called by muse, mutect2, varscan2
- TSNAX | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100791151; called by muse, mutect2, varscan2
- TTLL4 | c.1754dup p.T586Yfs*9 | Frame Shift Ins (INS) | VAF 47/216 reads (22%) | catalogued as rs1170236557; called by mutect2, pindel, varscan2
- TTN | c.9672G>T p.R3224S (on ENST00000591111; = p.R3178S on NM_003319.4) | Missense Mutation (SNP) | VAF 30/183 reads (16%) | PolyPhen benign (0.116); catalogued as COSV100630501, COSV59906165; called by muse, mutect2, varscan2
- UBAC1 | c.1165G>T p.G389W | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100873832; called by muse, mutect2, varscan2
- UGT2B28 | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 158/263 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100159086, COSV59432341; called by muse, mutect2, varscan2
- ULK2 | c.2956G>T p.E986* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100861020, COSV64448330; called by muse, mutect2, varscan2
- UMOD | c.1909C>G p.L637V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.211); catalogued as COSV100208310; called by muse, mutect2
- UNC45B | c.2761T>C p.C921R | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV99269327; called by muse, mutect2, varscan2
- USP17L2 | c.788C>A p.A263D | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100414785; called by muse, mutect2, varscan2
- USP30 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 93/274 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99980697; called by muse, mutect2, varscan2
- USP34 | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101277257; called by muse, mutect2
- USP9X | c.5024G>T p.G1675V | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100200193; called by muse, mutect2, varscan2
- VIRMA | c.3079G>C p.E1027Q | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.99); PolyPhen benign (0.147); catalogued as COSV99889644; called by muse, mutect2, varscan2
- WDCP | c.878A>G p.H293R | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs747118797, COSV54591842; called by muse, mutect2, varscan2
- WDR7 | c.3212C>A p.A1071E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99590592; called by muse, mutect2
- XCL1 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1270776832, COSV100892221; called by muse, mutect2, varscan2
- XPC | c.1498G>C p.A500P | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.765); catalogued as COSV99542715; called by muse, mutect2, varscan2
- ZIC1 | c.1168G>A p.G390S | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.097); catalogued as COSV99292532; called by muse, mutect2, varscan2
- ZNF324B | c.563A>T p.Q188L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as COSV100351828; called by muse, mutect2, varscan2
- ZNF471 | c.1666T>G p.S556A | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100340916; called by muse, mutect2, varscan2
- ZNF536 | c.2852G>T p.G951V | Missense Mutation (SNP) | VAF 163/350 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as COSV100836070, COSV62824295; called by muse, mutect2, varscan2
- ZNF563 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 95/393 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.131); catalogued as rs142547744; called by muse, mutect2, varscan2
- ZNF600 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 51/321 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV57746018; called by muse, mutect2, varscan2
- ZNF626 | c.1053G>C p.K351N | Missense Mutation (SNP) | VAF 109/161 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101657016; called by muse, mutect2, varscan2
- ZNF804A | c.1926G>C p.Q642H | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100168139, COSV100170470; called by muse, mutect2, varscan2
- ZNF804A | c.2805A>T p.E935D | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100170471; called by muse, mutect2, varscan2
- ZNF880 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | catalogued as COSV101425011; called by muse, mutect2, varscan2
- ZNRD2 | c.427G>C p.V143L | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100326236; called by muse, mutect2, varscan2
- ZP2 | c.1643C>T p.T548M | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99559891; called by muse, mutect2, varscan2
- ZP4 | c.596T>A p.V199E | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV100850793; called by muse, mutect2, varscan2
- ZSCAN29 | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99539504; called by muse, mutect2
- ADGRE1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.622); called by muse, mutect2
- ARID1B | c.5730_5737del p.S1912Rfs*16 | Frame Shift Del (DEL) | VAF 52/147 reads (35%) | called by pindel, varscan2
- BAIAP2L2 | c.1392del p.S465Afs*27 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel
- C11orf24 | c.858del p.T287Pfs*5 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- COL12A1 | c.8834G>T p.G2945V | Missense Mutation (SNP) | VAF 21/412 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD2 | c.577del p.L193Cfs*119 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | called by mutect2, pindel
- ETV3 | c.284+2_284+39del p.X95_splice | Splice Site (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- FLG2 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 9/259 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2
- FMN1 | c.3136_3137del p.K1046Dfs*19 (on ENST00000616417 / NM_001277313.2; = p.K823Dfs*19 on NM_001103184.4) | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by pindel, varscan2
- IGHV1-18 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- IGHV1-45 | c.252G>T p.Q84H | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 73/286 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- IL22RA1 | c.1453del p.E485Rfs*8 | Frame Shift Del (DEL) | VAF 38/149 reads (26%) | called by mutect2, pindel, varscan2
- ILDR2 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- IP6K2 | c.891dup p.Y298Vfs*5 | Frame Shift Ins (INS) | VAF 13/84 reads (15%) | called by mutect2, pindel, varscan2
- KCND1 | c.376_377insT p.E126Vfs*5 | Frame Shift Ins (INS) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- KIAA1109 | c.3232del p.I1078Lfs*7 | Frame Shift Del (DEL) | VAF 65/126 reads (52%) | called by mutect2, pindel, varscan2
- KRT82 | c.640del p.L214Cfs*12 | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | called by mutect2, pindel, varscan2
- LRRC7 | c.3759_3760delinsT p.R1254Gfs*35 (on ENST00000651989 / NM_001370785.2; = p.R1221Gfs*35 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | called by pindel, varscan2*
- MAGEB6B | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 95/134 reads (71%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MAP1LC3A | c.204-7_220del p.X68_splice | Splice Site (DEL) | VAF 26/234 reads (11%) | called by mutect2, pindel
- MMP28 | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR51A7 | c.780del p.M260Ifs*13 | Frame Shift Del (DEL) | VAF 89/394 reads (23%) | called by mutect2, pindel, varscan2
- OTOF | c.3203del p.R1068Pfs*78 (on ENST00000272371 / NM_194248.3; = p.R321Pfs*78 on NM_004802.4) | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel
- PRORP | c.1375del p.E459Rfs*42 | Frame Shift Del (DEL) | VAF 41/168 reads (24%) | called by mutect2, pindel*, varscan2
- RBP3 | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RCOR3 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RP1L1 | c.1179del p.V394Sfs*96 | Frame Shift Del (DEL) | VAF 42/121 reads (35%) | called by mutect2, pindel, varscan2
- TAF15 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- TP73 | c.232_252del p.R78_P84del | In Frame Del (DEL) | VAF 40/142 reads (28%) | called by mutect2, pindel, varscan2
- TTN | c.21652del p.E7218Sfs*38 (on ENST00000591111; = p.E6291Sfs*38 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 59/307 reads (19%) | called by mutect2, pindel, varscan2
- ZEB2 | c.2678del p.P893Lfs*37 | Frame Shift Del (DEL) | VAF 51/276 reads (18%) | called by mutect2, pindel, varscan2
- ZSWIM2 | c.1680del p.T561Lfs*3 | Frame Shift Del (DEL) | VAF 40/102 reads (39%) | called by mutect2, pindel, varscan2
- ABCC10 | c.3756G>A p.V1252= (on ENST00000372530 / NM_001198934.2; = p.V1224= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 63/406 reads (16%) | catalogued as rs1470053044, COSV99768063; called by muse, mutect2, varscan2
- ADCY2 | c.2586G>A p.A862= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as rs763078571, COSV57873344, COSV57875973; called by muse, mutect2, varscan2
- ADGRG1 | c.27G>C p.T9= | Silent (SNP) | VAF 44/75 reads (59%) | catalogued as COSV101113584; called by muse, mutect2, varscan2
- AFAP1L1 | c.2047C>A p.R683= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as COSV99696166, COSV99696183; called by muse, mutect2, varscan2
- ALYREF | c.486G>T p.R162= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV100485903; called by muse, mutect2, varscan2
- ATPAF2 | c.801C>T p.A267= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as rs762729719, COSV58264563; called by muse, mutect2, varscan2
- B3GNT6 | c.180G>A p.P60= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100845772; called by muse, mutect2, varscan2
- BAHCC1 | c.4428G>T p.R1476= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV100312111; called by muse, mutect2, varscan2
- BRS3 | c.1110G>T p.T370= | Silent (SNP) | VAF 67/92 reads (73%) | catalogued as COSV101036678; called by muse, mutect2, varscan2
- C12orf60 | c.228A>C p.A76= | Silent (SNP) | VAF 46/154 reads (30%) | catalogued as COSV99967010; called by muse, mutect2, varscan2
- C22orf42 | c.405C>A p.P135= | Silent (SNP) | VAF 67/107 reads (63%) | catalogued as COSV101173394; called by muse, mutect2, varscan2
- CACNA2D2 | c.420T>G p.A140= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV99818454; called by muse, mutect2, varscan2
- CACNA2D3 | c.843C>G p.S281= | Silent (SNP) | VAF 53/156 reads (34%) | catalogued as COSV99877714; called by muse, mutect2, varscan2
- CCBE1 | c.750C>A p.G250= | Silent (SNP) | VAF 29/150 reads (19%) | catalogued as rs1261317542, COSV101232879; called by muse, mutect2, varscan2
- CCR1 | c.168C>G p.V56= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99946816; called by muse, mutect2, varscan2
- CDH19 | c.1170C>A p.G390= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV100051616, COSV100052473; called by muse, mutect2, varscan2
- CDKN2B | c.90G>A p.V30= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs1459932063, COSV99439691; called by muse, mutect2, varscan2
- CEP131 | c.1953G>C p.V651= (on ENST00000269392 / NM_001319228.2; = p.V648= on NM_014984.4) | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV99489111; called by muse, mutect2, varscan2
- CHD5 | c.1860C>T p.D620= | Silent (SNP) | VAF 38/132 reads (29%) | catalogued as COSV99315296; called by muse, mutect2, varscan2
- CIAPIN1 | c.783G>A p.K261= | Silent (SNP) | VAF 45/81 reads (56%) | catalogued as COSV101275936; called by muse, mutect2, varscan2
- COL4A6 | c.981G>A p.G327= | Silent (SNP) | VAF 61/153 reads (40%) | catalogued as rs770568311, COSV100565115; called by muse, mutect2, varscan2
- COQ10B | c.285A>G p.V95= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV99827496; called by muse, mutect2, varscan2
- CRB1 | c.2811C>A p.A937= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100958087; called by muse, mutect2, varscan2
- CROT | c.525C>T p.S175= | Silent (SNP) | VAF 104/161 reads (65%) | catalogued as COSV100519724; called by muse, mutect2, varscan2
- CSF1R | c.1068C>T p.T356= | Silent (SNP) | VAF 90/194 reads (46%) | catalogued as rs1211113814, COSV99643304; called by muse, mutect2, varscan2
- CTNNA2 | c.1954A>C p.R652= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV100562209; called by muse, mutect2, varscan2
- DDN | c.1059G>T p.A353= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as rs745961256, COSV100305506; called by muse, mutect2, varscan2
- DDX18 | c.1350G>A p.L450= | Silent (SNP) | VAF 56/227 reads (25%) | catalogued as rs781406596, COSV99604861; called by muse, mutect2, varscan2
- DNAH8 | c.8850C>G p.L2950= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV100547340; called by muse, mutect2, varscan2
- DOCK1 | c.5373G>A p.T1791= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs776271316, COSV99733173; called by muse, mutect2
- DYSF | c.3804G>T p.G1268= | Silent (SNP) | VAF 40/145 reads (28%) | catalogued as COSV50639426, COSV99250804; called by muse, mutect2, varscan2
- EPHB2 | c.2811C>G p.A937= (on ENST00000400191 / NM_001309193.2; = p.A938= on NM_004442.7) | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV101007437; called by muse, mutect2, varscan2
- FAM83C | c.432C>A p.T144= | Silent (SNP) | VAF 84/277 reads (30%) | catalogued as rs1250261661, COSV100981735; called by muse, mutect2, varscan2
- FGFR1 | c.562C>T p.L188= (on ENST00000447712 / NM_023110.3; = p.L186= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/120 reads (46%) | catalogued as COSV100249418; called by muse, mutect2, varscan2
- FOXE1 | c.348C>T p.R116= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as rs747503369, COSV100909938, COSV100909999; called by muse, mutect2, varscan2
- FXR2 | c.828G>T p.G276= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as COSV100007337; called by muse, mutect2, varscan2
- FYB1 | c.2118A>G p.R706= (on ENST00000351578 / NM_199335.5; = p.R752= on NM_001465.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100686526; called by muse, mutect2, varscan2
- GBA3 | c.276C>T p.I92= | Silent (SNP) | VAF 69/132 reads (52%) | catalogued as COSV72438538; called by muse, mutect2, varscan2
- GBP7 | c.339G>A p.S113= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs775142914, COSV54008517; called by muse, mutect2, varscan2
- GPR158 | c.2622G>T p.P874= | Silent (SNP) | VAF 100/223 reads (45%) | catalogued as COSV100894383, COSV66274913; called by muse, mutect2, varscan2
- GRIK2 | c.2301C>A p.G767= | Silent (SNP) | VAF 53/214 reads (25%) | catalogued as COSV100029825; called by muse, mutect2, varscan2
- IGKV6D-41 | c.21C>T p.F7= | Silent (SNP) | VAF 21/93 reads (23%) | called by muse, mutect2, varscan2
- IL17RB | c.9C>T p.L3= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs746854566, COSV99861368; called by muse, mutect2, varscan2
- ITPRID1 | c.633G>T p.V211= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV100087696; called by muse, mutect2
- KCNA4 | c.1641G>T p.A547= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as rs368797575, COSV100069314; called by muse, mutect2, varscan2
- KIR2DL1 | c.708C>T p.S236= | Silent (SNP) | VAF 28/505 reads (6%) | catalogued as rs1370770277; called by muse, mutect2
- KRT33A | c.1071G>A p.R357= | Silent (SNP) | VAF 67/156 reads (43%) | catalogued as COSV99145029; called by muse, mutect2, varscan2
- KRTAP10-11 | c.840C>A p.P280= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV100555720; called by muse, mutect2, varscan2
- LMX1B | c.444G>T p.R148= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV100827310; called by muse, mutect2, varscan2
- MACF1 | c.9303G>T p.G3101= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV99247230; called by muse, mutect2, varscan2
- MAGEA6 | c.909C>A p.L303= | Silent (SNP) | VAF 124/182 reads (68%) | catalogued as COSV100263021; called by muse, mutect2, varscan2
- MAP3K3 | c.943C>T p.L315= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV100675658; called by muse, mutect2, varscan2
- MAP3K9 | c.3174G>A p.G1058= (on ENST00000554752 / NM_001284230.1; = p.G1072= on NM_033141.4) | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs546356633, COSV101173788; called by muse, mutect2, varscan2
- MCTP1 | c.2112G>T p.L704= | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as COSV100388364; called by muse, mutect2, varscan2
- MED12L | c.1230G>T p.P410= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV99854957; called by muse, mutect2, varscan2
- METTL21A | c.126C>A p.V42= | Silent (SNP) | VAF 31/156 reads (20%) | catalogued as COSV99777793; called by muse, mutect2, varscan2
- MS4A7 | c.138C>A p.T46= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV100279785; called by muse, mutect2, varscan2
- MST1R | c.1296C>T p.S432= | Silent (SNP) | VAF 42/172 reads (24%) | catalogued as rs779182367, COSV99619837; called by muse, mutect2, varscan2
- NEXN | c.784C>A p.R262= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as rs1002648603, COSV99630698; called by muse, mutect2, varscan2
- NIN | c.4503G>C p.T1501= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV99815570; called by muse, mutect2, varscan2
- NLRP12 | c.2709G>T p.L903= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV100145992; called by muse, mutect2, varscan2
- NLRP9 | c.2455C>T p.L819= | Silent (SNP) | VAF 69/164 reads (42%) | catalogued as COSV100243545; called by muse, mutect2, varscan2
- NPFFR1 | c.402G>T p.L134= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV99525044; called by muse, mutect2, varscan2
- OGG1 | c.66G>A p.L22= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV100115630; called by muse, mutect2, varscan2
- OR13G1 | c.906T>C p.F302= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as rs1158727184, COSV100687614; called by muse, mutect2, varscan2
- OR4K2 | c.51C>A p.L17= | Silent (SNP) | VAF 103/490 reads (21%) | catalogued as COSV100064807, COSV53850923; called by muse, mutect2, varscan2
- OR8J1 | c.408G>T p.V136= | Silent (SNP) | VAF 38/164 reads (23%) | catalogued as COSV100275244; called by muse, mutect2, varscan2
- PIGG | c.2919G>T p.T973= (on ENST00000453061 / NM_001127178.3; = p.T965= on NM_017733.4) | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as rs372154748, COSV99574428; called by muse, mutect2, varscan2
- PLA2G4E | c.2532T>C p.N844= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV101268654; called by muse, mutect2
- PLD5 | c.555A>T p.L185= (on ENST00000442594; = p.L123= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV100143237; called by muse, mutect2, varscan2
- POLE | c.3897G>A p.E1299= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV100268545; called by muse, mutect2
- POTEH | c.321C>G p.P107= | Silent (SNP) | VAF 152/1125 reads (14%) | catalogued as rs375385129; called by muse, varscan2
- PRDM9 | c.123A>T p.A41= | Silent (SNP) | VAF 93/221 reads (42%) | catalogued as COSV99691386; called by muse, mutect2, varscan2
- PRDX4 | c.780A>C p.P260= | Silent (SNP) | VAF 36/50 reads (72%) | catalogued as COSV101028813; called by muse, mutect2, varscan2
- PRKCG | c.1317G>T p.G439= | Silent (SNP) | VAF 51/89 reads (57%) | catalogued as COSV99669616; called by muse, mutect2, varscan2
- PROKR2 | c.198C>A p.V66= | Silent (SNP) | VAF 63/110 reads (57%) | catalogued as COSV54087638, COSV99450701; called by muse, mutect2, varscan2
- PRRC2B | c.3729C>T p.D1243= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV100622336; called by muse, mutect2, varscan2
- QDPR | c.177G>T p.S59= | Silent (SNP) | VAF 33/56 reads (59%) | catalogued as COSV99845984; called by muse, mutect2, varscan2
- QSOX1 | c.2157G>T p.L719= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100852970; called by muse, mutect2, varscan2
- RAB11FIP1 | c.654G>A p.K218= | Silent (SNP) | VAF 52/255 reads (20%) | catalogued as COSV54758672, COSV54763884, COSV99770575; called by muse, mutect2, varscan2
- RAG1 | c.192A>T p.A64= | Silent (SNP) | VAF 52/192 reads (27%) | catalogued as COSV100201194; called by muse, mutect2, varscan2
- RBM39 | c.729A>G p.Q243= | Silent (SNP) | VAF 65/172 reads (38%) | catalogued as COSV99488953; called by muse, mutect2, varscan2
- RHCG | c.1053C>A p.G351= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99174331; called by muse, mutect2, varscan2
- RNF216 | c.81C>T p.L27= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV101111398; called by muse, mutect2, varscan2
- RNF34 | c.204A>G p.S68= | Silent (SNP) | VAF 8/208 reads (4%) | catalogued as rs374454541; called by muse, mutect2
- RUVBL1 | c.1038C>T p.S346= | Silent (SNP) | VAF 43/105 reads (41%) | catalogued as rs1192112002, COSV100494270; called by muse, mutect2, varscan2
- RYR1 | c.4470C>T p.N1490= | Silent (SNP) | VAF 35/65 reads (54%) | catalogued as COSV62088148; called by muse, mutect2, varscan2
- SARDH | c.198G>A p.T66= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs572727005, COSV100061306; called by muse, mutect2, varscan2
- SCAF1 | c.15T>C p.D5= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99882156; called by muse, mutect2, varscan2
- SERPINA12 | c.576G>T p.L192= | Silent (SNP) | VAF 31/126 reads (25%) | catalogued as COSV100369851; called by muse, mutect2, varscan2
- SLC34A3 | c.1230G>C p.L410= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV100746725; called by muse, mutect2, varscan2
- SLC7A6OS | c.657C>T p.P219= | Silent (SNP) | VAF 44/71 reads (62%) | catalogued as COSV99546890; called by muse, mutect2, varscan2
- SLIT3 | c.276G>T p.L92= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as COSV100270359; called by muse, mutect2, varscan2
- SPATA31A3 | c.2139G>T p.S713= | Silent (SNP) | VAF 28/164 reads (17%) | catalogued as rs1342598681; called by muse, mutect2, varscan2
- STAG3 | c.2766T>C p.S922= | Silent (SNP) | VAF 7/145 reads (5%) | catalogued as COSV100426216; called by muse, mutect2
- TCL1B | c.93C>G p.T31= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100525882; called by muse, mutect2, varscan2
- TECRL | c.207A>C p.T69= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV101169452; called by muse, mutect2
- TEPSIN | c.1509G>A p.S503= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs548879060, COSV56143682; called by muse, mutect2, varscan2
- TEX15 | c.4401G>T p.A1467= (on ENST00000256246; = p.A1850= on NM_001350162.2) | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as COSV99821825, COSV99822248; called by muse, mutect2, varscan2
- TG | c.2301G>T p.G767= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV99603582; called by muse, mutect2, varscan2
- TLK1 | c.84G>A p.A28= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100688907; called by muse, mutect2
- TMEM165 | c.90G>T p.A30= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV101189691; called by muse, mutect2, varscan2
- TMTC1 | c.1968G>A p.L656= (on ENST00000539277 / NM_001193451.2; = p.L548= on NM_175861.3) | Silent (SNP) | VAF 72/313 reads (23%) | catalogued as rs1261144263, COSV99761262; called by muse, mutect2, varscan2
- TRIM11 | c.1305G>T p.S435= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99489092; called by muse, mutect2, varscan2
- TTC9B | c.165C>A p.G55= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99454935; called by muse, mutect2, varscan2
- VCAN | c.534C>A p.V178= | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as COSV99427540; called by muse, mutect2, varscan2
- WDTC1 | c.750C>T p.Y250= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as rs764422484, COSV100089635; called by muse, mutect2, varscan2
- WFS1 | c.1770G>A p.T590= | Silent (SNP) | VAF 55/102 reads (54%) | catalogued as rs71532858, COSV56990001; ClinVar: likely benign; called by muse, mutect2, varscan2
- WNT7A | c.510G>A p.R170= | Silent (SNP) | VAF 58/218 reads (27%) | catalogued as COSV99541801; called by muse, mutect2, varscan2
- ZBED9 | c.327G>A p.Q109= | Silent (SNP) | VAF 38/251 reads (15%) | catalogued as rs1473582794, COSV101509410; called by muse, mutect2, varscan2
- ZNF107 | c.2025A>T p.L675= | Silent (SNP) | VAF 40/60 reads (67%) | catalogued as rs1340567639, COSV100788550, COSV61329166; called by muse, mutect2, varscan2
- ZNF292 | c.3345T>C p.I1115= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV100371438; called by muse, mutect2, varscan2
- ZNF532 | c.498G>T p.G166= | Silent (SNP) | VAF 59/227 reads (26%) | catalogued as COSV100267240; called by muse, mutect2, varscan2
- ZNF804A | c.1158C>A p.S386= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV100170468; called by muse, mutect2, varscan2
- ZNF808 | c.1614T>C p.S538= | Silent (SNP) | VAF 169/382 reads (44%) | catalogued as COSV100708250; called by muse, mutect2, varscan2
- ZNF98 | c.711C>A p.P237= | Silent (SNP) | VAF 9/24 reads (38%) | called by mutect2, varscan2
- ZZEF1 | c.4416C>T p.A1472= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs780115088, COSV101068157; called by muse, mutect2, varscan2
- AC024940.1 | n.4457A>G | RNA (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73826036 G>A | 5'Flank (SNP) | VAF 111/150 reads (74%) | called by muse, mutect2, varscan2
- BX119917.1 | n.186C>G | RNA (SNP) | VAF 36/53 reads (68%) | catalogued as rs754522531; called by muse, mutect2, varscan2
- CBX2 | c.288+114G>A | Intron (SNP) | VAF 20/153 reads (13%) | catalogued as rs1219262935, COSV99491045; called by muse, mutect2, varscan2
- DHRS12 | c.706+345G>A | Intron (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99524021; called by muse, mutect2, varscan2
- FGFR3 | c.*187C>T | 3'UTR (SNP) | VAF 9/211 reads (4%) | catalogued as COSV53395819; called by muse, mutect2
- GREB1 | c.1160-1332C>T | Intron (SNP) | VAF 29/91 reads (32%) | catalogued as COSV99303946; called by muse, mutect2, varscan2
- GYPC | c.*1G>A | 3'UTR (SNP) | VAF 21/42 reads (50%) | catalogued as rs745348448, COSV99392112; called by muse, mutect2, varscan2
- HEXD | c.*75G>A | 3'UTR (SNP) | VAF 14/108 reads (13%) | catalogued as rs764512990, COSV100028080; called by muse, mutect2, varscan2
- MIR516B1 | n.24G>A | RNA (SNP) | VAF 38/215 reads (18%) | catalogued as rs1036250436; called by muse, mutect2, varscan2
- MIR520H | n.85G>T | RNA (SNP) | VAF 21/113 reads (19%) | called by muse, mutect2, varscan2
- OR6N1 | c.-2C>A | 5'UTR (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100625313; called by muse, mutect2
- SNORD115-21 | n.19T>A | RNA (SNP) | VAF 77/361 reads (21%) | called by muse, mutect2, varscan2
- SSPOP | n.13324G>T | RNA (SNP) | VAF 90/107 reads (84%) | catalogued as COSV65134508; called by muse, mutect2, varscan2
